Gene-level copy-number profile of specimen HCM-BROD-0643-C43-85N from HCMI case HCM-BROD-0643-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 53.6 years (19,588 days).
Specimen HCM-BROD-0643-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9600e856-3b10-4bec-a630-23d3f315b8a9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0643-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/312697d7-51b3-4fb7-854e-77a24caab044

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,797; copy number 2: 32,226; copy number 3: 10,989; copy number 4: 2,385; copy number 5: 65; copy number 6: 393; copy number 7: 49.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 507 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,126,974–120,127,074, 1 gene, copy number 5: RNU6-465P.
- chr2:88,811,186–88,861,563, 2 genes, copy number 5 (within-gene range 4–7): MALLP2, AC244205.1.
- chr2:88,857,161–89,600,680, 49 genes, copy number 7 (within-gene range 5–7): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr2:90,154,073–91,580,863, 14 genes, copy number 5: IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2.
- chr2:144,666,312–145,262,988, 1 gene, copy number 5 (within-gene range 4–5): TEX41.
- chr7:24,796,540–25,188,724, 5 genes, copy number 5: OSBPL3, SNRPCP19, CYCS, C7orf31, AC004129.2.
- chr11:66,682,497–78,139,653, 400 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr22:22,484,421–22,580,296, 5 genes, copy number 5: ZNF280B, ZNF280A, PRAME, LL22NC03-63E9.3, IGLV2-34.
- chr22:22,686,726–22,838,872, 29 genes, copy number 5: IGLV3-25, AC244250.2, AC244250.1, IGLV3-24, IGLV2-23, IGLVVI-22-1, IGLV3-22, IGLV3-21, IGLVI-20, IGLV3-19, AC244250.3, IGLV2-18, IGLV3-17, IGLV3-16, IGLV3-15, IGLV2-14, IGLV3-13, IGLV3-12, AC244157.1, AC244157.2, IGLV2-11, AC245028.3, IGLV3-10, AC245028.1, IGLV3-9, IGLV2-8, MIR650, AC245028.2, IGLV3-7.
- chr22:22,887,780–22,896,111, 1 gene, copy number 5 (within-gene range 2–5): IGLL5.

Autosomal genes at a single copy (total copy number 1): 9,941. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
